Gene-level copy-number profile of tumor specimen TCGA-DQ-5624-01A from TCGA case TCGA-DQ-5624, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; Tumor grade: G2; Age at diagnosis: 43.4 years (15,867 days).
Specimen TCGA-DQ-5624-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.49d97753-6292-42a0-9e4b-bcb9e52e29b2.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DQ-5624-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/319a64ba-25ed-4203-b343-3de86a11c787

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 1,025; copy number 2: 5,308; copy number 3: 16,598; copy number 4: 27,655; copy number 5: 2,327; copy number 6: 3,237; copy number 7: 1,858; copy number 8: 58; copy number 9: 1,334; copy number 10: 18; copy number 11: 47; copy number 13: 72; copy number 14: 39; copy number 15: 26; copy number 16: 3; copy number 17: 13; copy number 18: 51; copy number 19: 5; copy number 21: 31; copy number 22: 44; copy number 27: 14; copy number 36: 54.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DQ-5624-01A-01D-1869-01): tumor purity 0.27, ploidy 3.82, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:3,700,492–3,700,628, 1 gene: RNA5SP251.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,751 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:24,729,379–26,013,025, 21 genes, copy number 10–16: AC091893.2, AC091893.1, AC106821.2, BTG4P1, SNORD29, LINC02239, AC106821.1, Y_RNA, LINC02228, LINC02211, AC099499.2, AC099499.1, AC106754.1, AC106754.2, AC022140.1, AC022140.2, RNU6-374P, AC022418.1, MSNP1, AC113370.1, RNU4-43P.
- chr6:6,588,108–8,343,139, 39 genes, copy number 9–27 (within-gene range 2–27): LY86, AL031123.2, AL031123.3, AL031123.1, AL031123.4, AL031123.5, AL136361.1, BTF3P7, AL158817.1, RN7SL554P, AL139390.1, RREB1, AL355336.1, Y_RNA, AL589644.1, AL139095.5, SSR1, AL139095.4, CAGE1, AL139095.1, AL139095.2, AL139095.3, RIOK1, HNRNPLP1, AL138878.1, AL138878.2, AL031058.1, DSP, SNRNP48, AL390026.1, BMP6, TXNDC5, BLOC1S5-TXNDC5, AL096800.1, PIP5K1P1, BLOC1S5, EEF1E1-BLOC1S5, EEF1E1, AL355499.1.
- chr7:53,559,214–57,485,895, 142 genes, copy number 11–36 (broad region; genes not listed).
- chr8:73,215,929–145,066,685, 1,129 genes, copy number 9 (broad region; genes not listed).
- chr10:36,432,882–38,466,176, 49 genes, copy number 9–19: MTND5P17, MTND4P18, AL590730.1, AL590730.2, NAMPTP1, Y_RNA, AL390061.1, MKNK2P1, ARL6IP1P2, ANKRD30A, RNU6-811P, AL157387.1, LINC00993, RN7SL314P, Y_RNA, TMEM161BP1, VN1R53P, TACC1P1, MTND1P18, MTRNR2L7, AL132657.1, ZNF248, AL132657.2, ZNF33BP1, TLK2P2, AL135791.1, ZNF37CP, ZNF33CP, ZNF25, ZNF25-DT, Y_RNA, ZNF33A, RNU6-795P, AL161931.1, EIF3LP3, FXYD6P2, ZNF37A, AL117339.4, AL117339.3, AL117339.1, CCNYL4, AL133217.1, AL117339.2, HSD17B7P2, SEPTIN7P9, AL133216.2, RNU6-1118P, CICP9, AL133216.1.
- chr12:55,283,750–61,702,771, 215 genes, copy number 9–14 (broad region; genes not listed).
- chr12:61,775,923–61,880,772, 2 genes, copy number 14: RPL21P104, KRT8P19.
- chr12:63,558,913–66,130,750, 72 genes, copy number 13 (within-gene range 3–13) (broad region; genes not listed).
- chr13:70,923,664–73,227,260, 26 genes, copy number 11–15: MTCL1P1, LINC00348, RABEPKP1, DACH1, H3P36, RPL21P109, RPL35AP31, RPS10P21, AL139003.1, RPL18AP17, AL139003.2, AL356754.2, AL356754.1, RPL21P110, RNU6-80P, MZT1, BORA, DIS3, PIBF1, RNU6-79P, PSMD10P3, KLF5, FABP5P1, RNU6-66P, RNU4-10P, RNY1P8.
- chr13:76,552,807–77,975,529, 27 genes, copy number 21: AL136441.1, AL161717.1, AL365394.1, KCTD12, AC000403.1, BTF3P11, ACOD1, RPL7P44, DHX9P1, CLN5, AC001226.2, FBXL3, MYCBP2-AS1, AC001226.1, MYCBP2, MYCBP2-AS2, AL159158.1, SCEL, AL137140.1, SCEL-AS1, RNY3P7, SPTLC1P5, AL450447.1, SLAIN1, MIR3665, EDNRB-AS1, EDNRB.
- chr13:77,939,016–78,053,604, 4 genes, copy number 21: AL139002.1, RN7SL810P, LINC01069, LINC00446.
- chr17:34,574,123–35,121,493, 12 genes, copy number 11 (within-gene range 3–11): C17orf102, TMEM132E, AC005691.1, AC005552.1, AC022903.1, CCT6B, AC022903.2, ZNF830, LIG3, RFFL, AC004223.3, AC004223.4.
- chr17:58,301,228–58,557,799, 13 genes, copy number 17 (within-gene range 4–17): TSPOAP1, TSPOAP1-AS1, AC004687.1, MIR142, MIR4736, SUPT4H1, AC004687.2, RNF43, HSF5, SETP3, MTMR4, SEPTIN4-AS1, SEPTIN4.

Autosomal genes at a single copy (total copy number 1): 1,025. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
